TCGA case TCGA-HZ-A49H — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/17142718-742e-464a-8e0f-a6b9ac8fad75

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 68.1 years (24,891 days); Year of diagnosis: 2012; Method of diagnosis: Cytology; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 491 days (1.3 years); Sites of involvement: Pancreas Head; Tumor grade category: Four Tier.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 44; Tumor largest dimension diameter: 2.8 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 121 days; Days to treatment end: 207 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Whipple.

Follow-up (2 entries)
- Days to follow up: 29 days; Disease response: Tumor Free.
- Days to follow up: 491 days (1.3 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HZ-A49H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-HZ-A49H-01A-01-TS1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 10; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-HZ-A49H-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HZ-A49H-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tumor status: Tumor free; Alcohol history documented: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 491 days; disease-specific survival: no event (censored), 491 days; disease-free interval: no event (censored), 491 days; progression-free interval: no event (censored), 491 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HZ-A49H-01A-11D-A26H-01): tumor purity 1, ploidy 2, whole-genome doublings 0.
